Somatic mutation profile of tumor specimen TCGA-36-2547-01A (aliquot TCGA-36-2547-01A-01D-1526-09) from TCGA case TCGA-36-2547, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 64.9 years (23,706 days).
Specimen TCGA-36-2547-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd746800-6542-4306-982e-9ec3c8d264ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2547-10A (Blood Derived Normal), aliquot TCGA-36-2547-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0251ab1-112e-4af9-936e-586eb768d12f

The open-access MAF lists 161 somatic variants for this specimen: 127 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 31, Frame Shift Del 9, Nonsense Mutation 7, Splice Site 2, Splice Region 1, In Frame Del 1, Intron 1, Nonstop Mutation 1, 5'Flank 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC098582.1 | c.968C>G p.A323G | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52021234; called by muse, mutect2, varscan2
- ACSF2 | c.368A>T p.K123I | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99366172; called by muse, mutect2
- ADAMTS12 | c.1880T>G p.F627C | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.719); catalogued as COSV61265823; called by muse, mutect2, varscan2
- ALDH1A3 | c.99G>C p.K33N | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV60902037; called by muse, varscan2
- ALK | c.3562C>T p.Q1188* | Nonsense Mutation (SNP) | VAF 47/135 reads (35%) | catalogued as COSV101201955; called by muse, mutect2, varscan2
- ANK1 | c.1022C>A p.P341Q | Missense Mutation (SNP) | VAF 214/565 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55884458; called by muse, mutect2, varscan2
- ANKRD55 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV61947489; called by muse, mutect2, varscan2
- ANOS1 | c.1669T>C p.S557P | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV52921470; called by muse, mutect2, varscan2
- APOL5 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.468); catalogued as rs1388608877, COSV50767191; called by muse, mutect2, varscan2
- AR | c.2729G>T p.G910V | Missense Mutation (SNP) | VAF 103/304 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65953743, COSV65958355; called by muse, mutect2, varscan2
- ARHGEF1 | c.2266A>C p.T756P | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV61528185; called by muse, mutect2, varscan2
- ASPRV1 | c.599G>C p.G200A | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100208495; called by muse, mutect2
- B3GAT3 | c.99C>A p.C33* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as COSV55489081, COSV55489093; called by muse, mutect2, varscan2
- BCL2L2 | c.100G>T p.G34W | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV51636146; called by muse, mutect2, varscan2
- BRMS1 | c.503A>C p.E168A | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV60820263; called by muse, mutect2, varscan2
- CAPN5 | c.1240G>A p.G414S (on ENST00000456580; = p.G374S on NM_004055.5) | Missense Mutation (SNP) | VAF 73/425 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782148894, COSV53688860; called by muse, mutect2, varscan2
- CCDC60 | c.1134C>G p.Y378* | Nonsense Mutation (SNP) | VAF 89/572 reads (16%) | catalogued as COSV59545423; called by muse, mutect2, varscan2
- CELSR2 | c.4342A>C p.S1448R | Missense Mutation (SNP) | VAF 98/511 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54773898; called by muse, mutect2, varscan2
- CEP72 | c.1742T>A p.I581N | Missense Mutation (SNP) | VAF 103/586 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as rs776716241, COSV53793725; called by muse, mutect2, varscan2
- CHPF | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 119/457 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs377574209, COSV60535145; called by muse, mutect2, varscan2
- CLEC4A | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 244/698 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV57562078; called by muse, mutect2, varscan2
- COL15A1 | c.2299G>A p.G767R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66642864, COSV66646208; called by muse, mutect2, varscan2
- COL7A1 | c.8290G>A p.E2764K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs141883531; called by muse, mutect2, varscan2
- COX7A2L | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 86/463 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as rs757464832, COSV52243328; called by muse, mutect2, varscan2
- CPNE2 | c.1547_1548del p.K516Rfs*22 | Frame Shift Del (DEL) | VAF 122/343 reads (36%) | catalogued as rs770161727; called by mutect2, pindel, varscan2
- CRACR2A | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 128/980 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV52912528, COSV52914186; called by muse, varscan2
- DISP1 | c.3637A>C p.T1213P | Missense Mutation (SNP) | VAF 116/131 reads (89%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs765153780, COSV52660547; called by muse, mutect2, varscan2
- DSC1 | c.2201T>C p.I734T | Missense Mutation (SNP) | VAF 146/298 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57146906; called by muse, mutect2, varscan2
- EFCAB14 | c.1419G>T p.L473F | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV61906260; called by muse, mutect2, varscan2
- EGFLAM | c.2743A>G p.M915V (on ENST00000354891 / NM_001205301.2; = p.M907V on NM_152403.4) | Missense Mutation (SNP) | VAF 73/470 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs776793514, COSV59305941; called by muse, mutect2, varscan2
- EIF2S2 | c.886C>G p.R296G | Missense Mutation (SNP) | VAF 69/857 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66621601, COSV66622263; called by muse, mutect2
- EIF2S2 | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 90/631 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as COSV66621766; called by muse, mutect2, varscan2
- EMILIN3 | c.1211C>A p.A404E | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV60036904; called by muse, mutect2, varscan2
- ENPP3 | c.1924A>T p.M642L | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62954735; called by muse, mutect2, varscan2
- FABP7 | c.314T>A p.F105Y | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV62956677; called by muse, mutect2, varscan2
- FAM214B | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1376321196, COSV59716614; called by muse, mutect2, varscan2
- FIG4 | c.765T>G p.C255W | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57788433; called by muse, mutect2, varscan2
- GABRR2 | c.1098G>C p.M366I | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV68765222; called by muse, mutect2, varscan2
- GLI1 | c.1247G>C p.R416T | Missense Mutation (SNP) | VAF 91/269 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.035); catalogued as COSV57363597, COSV99954206; called by muse, mutect2, varscan2
- GUSB | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 73/390 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as COSV59222240; called by muse, mutect2, varscan2
- HCRTR2 | c.99C>G p.D33E | Missense Mutation (SNP) | VAF 94/762 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV63796539; called by muse, mutect2, varscan2
- HOXC11 | c.670G>C p.G224R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.131); catalogued as COSV54533494; called by muse, mutect2, varscan2
- IL17RC | c.2116G>C p.D706H (on ENST00000295981 / NM_153461.4; = p.D620H on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55973617; called by muse, mutect2, varscan2
- JAKMIP1 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 91/242 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs746368286, COSV51530199; called by muse, mutect2, varscan2
- KBTBD7 | c.1482G>A p.M494I | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV65266663; called by muse, mutect2, varscan2
- KCNH4 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 10/206 reads (5%) | catalogued as rs1371556166, COSV99237144; called by muse, mutect2
- KIFC3 | c.1302G>C p.K434N | Missense Mutation (SNP) | VAF 62/355 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV65551024; called by muse, mutect2, varscan2
- LAMA3 | c.8863C>G p.L2955V (on ENST00000313654 / NM_198129.4; = p.L1346V on NM_000227.6) | Missense Mutation (SNP) | VAF 62/588 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.034); catalogued as COSV52536670; called by muse, varscan2
- LMBRD2 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); catalogued as COSV56950721; called by muse, mutect2, varscan2
- LMTK2 | c.194G>A p.C65Y | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51996705, COSV99807472; called by muse, mutect2, varscan2
- LRP1 | c.11839C>T p.R3947W | Missense Mutation (SNP) | VAF 42/358 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs771295238, COSV54514834; called by muse, mutect2, varscan2
- LSAMP | c.706T>A p.S236T | Missense Mutation (SNP) | VAF 181/866 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV61295598; called by muse, mutect2, varscan2
- MACF1 | c.17750T>A p.I5917N (on ENST00000372915; = p.I3962N on NM_012090.5) | Missense Mutation (SNP) | VAF 139/437 reads (32%) | catalogued as COSV57127146; called by muse, mutect2, varscan2
- MAP1S | c.2152A>T p.S718C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV60723165; called by muse, mutect2, varscan2
- MATR3 | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 73/127 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as rs759801664, COSV63077900; called by muse, mutect2, varscan2
- MBOAT1 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 145/1096 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61125930; called by muse, mutect2, varscan2
- MORC1 | c.367A>T p.T123S | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as rs1156648861, COSV51722274; called by muse, mutect2, varscan2
- MSH4 | c.2531G>C p.G844A | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54204899, COSV54210661; called by muse, mutect2, varscan2
- MTMR8 | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66394534, COSV66396093; called by muse, mutect2, varscan2
- MYD88 | c.858G>C p.W286C | Missense Mutation (SNP) | VAF 243/480 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57175471; called by muse, mutect2, varscan2
- MYH9 | c.4165A>C p.K1389Q | Missense Mutation (SNP) | VAF 65/299 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV53387915; called by muse, mutect2, varscan2
- NEK10 | c.3326C>A p.S1109Y | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.422); catalogued as COSV55360240; called by muse, mutect2, varscan2
- NOLC1 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53386227; called by muse, mutect2, varscan2
- NOP56 | c.1491A>C p.E497D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV61390356; called by muse, mutect2, varscan2
- NPBWR2 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 64/313 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV63900264; called by muse, mutect2, varscan2
- NPPB | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 68/98 reads (69%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV64687643; called by muse, mutect2, varscan2
- OR13G1 | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV62944472; called by muse, mutect2, varscan2
- OR14C36 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 126/644 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV100507516; called by muse, varscan2
- OR1B1 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100506469; called by muse, mutect2
- OR2T12 | c.51C>G p.N17K | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV58777935; called by muse, mutect2, varscan2
- OR4A47 | c.664T>C p.S222P | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as rs763200828, COSV71445024; called by muse, mutect2, varscan2
- OS9 | c.1780A>C p.K594Q | Missense Mutation (SNP) | VAF 104/190 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57729028; called by muse, mutect2, varscan2
- PAMR1 | c.1703A>T p.D568V (on ENST00000619888 / NM_001001991.3; = p.D585V on NM_015430.4) | Missense Mutation (SNP) | VAF 73/278 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53513564; called by muse, mutect2, varscan2
- PARP1 | c.2695G>A p.D899N | Missense Mutation (SNP) | VAF 149/883 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64690946, COSV64691048; called by muse, mutect2, varscan2
- PEX5 | c.1265C>A p.A422D (on ENST00000420616; = p.A414D on NM_000319.5) | Missense Mutation (SNP) | VAF 64/486 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56955870; called by muse, varscan2
- PGM2L1 | c.1540A>T p.K514* | Nonsense Mutation (SNP) | VAF 23/85 reads (27%) | catalogued as COSV53347576; called by muse, mutect2, varscan2
- PIGR | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 242/405 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62904280; called by muse, mutect2, varscan2
- PMM2 | c.250A>G p.R84G | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV51632315; called by muse, mutect2, varscan2
- PSG3 | c.1075A>C p.N359H | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV59504977; called by muse, mutect2, varscan2
- PSMD1 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 20/112 reads (18%) | catalogued as COSV58079915; called by muse, mutect2, varscan2
- PTPN4 | c.2452T>C p.W818R | Missense Mutation (SNP) | VAF 78/480 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55303493; called by muse, mutect2, varscan2
- RCBTB1 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.403); catalogued as COSV99319502; called by muse, mutect2
- RECK | c.2398G>T p.A800S | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65035615; called by muse, mutect2, varscan2
- RHAG | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 129/461 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV57704868, COSV57706417; called by muse, mutect2, varscan2
- RHOBTB3 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV66102351; called by muse, mutect2, varscan2
- RNASEL | c.1978G>T p.G660C | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV62377144; called by muse, mutect2, varscan2
- RNF220 | c.617A>T p.N206I | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV62407183; called by muse, mutect2, varscan2
- RPUSD4 | c.529A>G p.R177G | Missense Mutation (SNP) | VAF 33/379 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV100028718; called by muse, mutect2
- RRBP1 | c.3043G>C p.V1015L (on ENST00000377813 / NM_001365613.2; = p.V582L on NM_004587.3) | Missense Mutation (SNP) | VAF 75/634 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV55701965; called by muse, mutect2, varscan2
- SERTAD2 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 25/135 reads (19%) | catalogued as COSV57640510; called by muse, mutect2, varscan2
- SHE | c.1189C>G p.H397D | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59070684, COSV59072090; called by muse, mutect2, varscan2
- SHOX2 | c.386G>C p.G129A (on ENST00000441443 / NM_006884.3; = p.G153A on NM_003030.4) | Missense Mutation (SNP) | VAF 40/391 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV101273804, COSV67464069; called by muse, mutect2, varscan2
- SLC25A12 | c.1454A>C p.K485T | Missense Mutation (SNP) | VAF 63/109 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV55534224; called by muse, mutect2, varscan2
- SLC5A9 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 141/516 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52584082; called by muse, mutect2, varscan2
- SMC3 | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV62420601; called by muse, mutect2, varscan2
- SRRM1 | c.2098G>A p.V700I | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs142386020; called by muse, varscan2
- SSH1 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs746073193, COSV58457201; called by muse, mutect2, varscan2
- SSRP1 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 234/461 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV53480043; called by muse, mutect2, varscan2
- STIL | c.3489G>C p.Q1163H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as COSV54551044; called by muse, mutect2, varscan2
- TG | c.1793T>G p.V598G | Missense Mutation (SNP) | VAF 80/377 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55080663; called by muse, mutect2, varscan2
- THAP10 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV51436698; called by muse, mutect2, varscan2
- TNC | c.4897C>A p.P1633T | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.217); catalogued as COSV100405467, COSV60786022; called by muse, varscan2
- TOP3A | c.2455G>T p.A819S | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as rs755043610, COSV58178434; called by muse, mutect2, varscan2
- TP53 | c.844_845insCGCCG p.R282Pfs*65 | Frame Shift Ins (INS) | VAF 102/143 reads (71%) | catalogued as COSV53688964; called by mutect2, pindel, varscan2
- TRPC6 | c.1024G>C p.V342L | Missense Mutation (SNP) | VAF 107/459 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV60256383; called by muse, mutect2, varscan2
- TSHZ1 | c.791A>G p.H264R (on ENST00000580243 / NM_001308210.2; = p.H219R on NM_005786.6) | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59011391; called by muse, mutect2, varscan2
- UBA1 | c.3124G>A p.D1042N | Missense Mutation (SNP) | VAF 266/485 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.151); catalogued as COSV60113385; called by muse, mutect2, varscan2
- USH2A | c.14915G>A p.R4972H | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs554061688, COSV56385365; called by muse, mutect2, varscan2
- UTP11 | c.658C>G p.Q220E | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.306); catalogued as COSV65951523; called by muse, mutect2, varscan2
- WDFY3 | c.4657C>G p.L1553V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.299); catalogued as COSV55704021, COSV99078494; called by muse, mutect2, varscan2
- WDR18 | c.895C>G p.Q299E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs868734921, COSV52122213; called by muse, mutect2, varscan2
- YIPF6 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV65855894; called by muse, mutect2, varscan2
- ZBTB37 | c.1023+3A>G | Splice Region (SNP) | VAF 114/456 reads (25%) | catalogued as COSV62932905; called by muse, mutect2, varscan2
- ZNF638 | c.1835C>T p.T612I | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV52489494; called by muse, mutect2, varscan2
- ACTR1A | c.1108_*8del | Nonstop Mutation (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- CHIC1 | c.362_377del p.E121Afs*5 | Frame Shift Del (DEL) | VAF 55/190 reads (29%) | called by mutect2, pindel, varscan2
- CLEC3B | c.24_31del p.L9Pfs*34 | Frame Shift Del (DEL) | VAF 40/139 reads (29%) | called by mutect2, pindel, varscan2
- KCNJ3 | c.1011_1024del p.F337Lfs*9 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | called by mutect2, pindel, varscan2
- LMLN | c.1945_1964del p.F649Lfs*18 | Frame Shift Del (DEL) | VAF 57/630 reads (9%) | called by mutect2, pindel
- MRC1 | c.3562T>C p.S1188P | Missense Mutation (SNP) | VAF 163/470 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- NIN | c.3472_3503del p.T1158Qfs*6 | Frame Shift Del (DEL) | VAF 48/130 reads (37%) | called by mutect2, pindel
- PHACTR3 | c.938_947del p.R313Kfs*51 | Frame Shift Del (DEL) | VAF 19/110 reads (17%) | called by mutect2, pindel, varscan2
- PRKG1 | c.584_592+35del p.X195_splice | Splice Site (DEL) | VAF 24/125 reads (19%) | called by mutect2, pindel
- SLC28A1 | c.557_594del p.C186Sfs*109 | Frame Shift Del (DEL) | VAF 70/678 reads (10%) | called by mutect2, pindel
- TACR1 | c.100_123del p.L34_V41del | In Frame Del (DEL) | VAF 73/427 reads (17%) | called by mutect2, pindel, varscan2
- TRPC6 | c.1511-25_1511-1del p.X504_splice | Splice Site (DEL) | VAF 28/103 reads (27%) | called by mutect2, pindel
- ZNF691 | c.499del p.E167Kfs*28 (on ENST00000372502; = p.E136Kfs*28 on NM_015911.3) | Frame Shift Del (DEL) | VAF 49/251 reads (20%) | called by mutect2, pindel, varscan2
- ABCA4 | c.1581C>T p.S527= | Silent (SNP) | VAF 66/188 reads (35%) | catalogued as COSV64674433; called by muse, mutect2, varscan2
- ABCB4 | c.969C>G p.V323= | Silent (SNP) | VAF 76/257 reads (30%) | catalogued as rs754961007, COSV55936485, COSV55936705; called by muse, mutect2, varscan2
- AK1 | c.474A>G p.E158= | Silent (SNP) | VAF 88/356 reads (25%) | catalogued as COSV56345317; called by muse, varscan2
- AKR7L | c.990C>T p.I330= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as COSV70167605; called by muse, mutect2, varscan2
- ALK | c.3561G>C p.L1187= | Silent (SNP) | VAF 47/134 reads (35%) | catalogued as COSV101201956; called by muse, mutect2, varscan2
- ASL | c.93C>T p.D31= | Silent (SNP) | VAF 68/338 reads (20%) | catalogued as COSV59188613; called by muse, mutect2, varscan2
- CDK14 | c.627G>A p.V209= (on ENST00000380050 / NM_001287135.2; = p.V191= on NM_012395.3) | Silent (SNP) | VAF 7/218 reads (3%) | catalogued as COSV99725196; called by muse, mutect2
- CSDE1 | c.18C>T p.N6= | Silent (SNP) | VAF 26/149 reads (17%) | catalogued as COSV54750084; called by muse, mutect2, varscan2
- CTPS2 | c.1143A>G p.K381= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV63722959; called by muse, mutect2, varscan2
- DMD | c.11025C>A p.T3675= | Silent (SNP) | VAF 104/321 reads (32%) | catalogued as COSV58919670; called by muse, mutect2, varscan2
- FBXL13 | c.1332C>A p.L444= | Silent (SNP) | VAF 48/538 reads (9%) | catalogued as COSV100501574; called by muse, mutect2
- GPR84 | c.1002C>A p.P334= | Silent (SNP) | VAF 126/484 reads (26%) | catalogued as COSV57209875; called by muse, varscan2
- HEPH | c.366C>G p.P122= (on ENST00000343002; = p.P176= on NM_138737.5) | Silent (SNP) | VAF 46/135 reads (34%) | catalogued as COSV57965785, COSV57968090; called by muse, mutect2, varscan2
- ITIH6 | c.1551C>T p.G517= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV54490300, COSV54493764; called by muse, mutect2, varscan2
- KIAA1841 | c.591C>T p.D197= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as rs756973200, COSV99693666; called by mutect2, varscan2
- LAMA1 | c.502A>C p.R168= | Silent (SNP) | VAF 254/395 reads (64%) | catalogued as COSV67531333, COSV67543103; called by muse, varscan2
- MYO1D | c.1686G>C p.L562= | Silent (SNP) | VAF 70/93 reads (75%) | catalogued as COSV59010915; called by muse, mutect2, varscan2
- NLRP3 | c.1053G>A p.V351= | Silent (SNP) | VAF 60/103 reads (58%) | catalogued as rs1473898388, COSV60226195; called by muse, mutect2, varscan2
- NPFFR2 | c.1278C>T p.G426= | Silent (SNP) | VAF 5/106 reads (5%) | catalogued as rs1376409831, COSV100440681; called by muse, mutect2
- NR2F1 | c.1114C>T p.L372= | Silent (SNP) | VAF 68/188 reads (36%) | catalogued as COSV59068975; called by muse, mutect2, varscan2
- PCDHB14 | c.1836C>T p.P612= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as rs781857021, COSV53389009; called by muse, mutect2, varscan2
- PEX26 | c.888T>G p.S296= | Silent (SNP) | VAF 271/615 reads (44%) | catalogued as COSV61604666; called by muse, varscan2
- RAB3GAP1 | c.2040C>T p.L680= | Silent (SNP) | VAF 130/157 reads (83%) | catalogued as COSV51483833; called by muse, mutect2, varscan2
- RHOXF2 | c.186G>A p.S62= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs374278020, COSV65047876; called by muse, mutect2, varscan2
- RREB1 | c.2940T>G p.P980= | Silent (SNP) | VAF 58/206 reads (28%) | catalogued as COSV58559679; called by muse, mutect2, varscan2
- SCN2B | c.45G>T p.T15= | Silent (SNP) | VAF 97/468 reads (21%) | catalogued as COSV54050824; called by muse, mutect2, varscan2
- SLC7A3 | c.393C>T p.A131= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV99979549; called by muse, mutect2
- TLN2 | c.3999G>A p.A1333= | Silent (SNP) | VAF 28/302 reads (9%) | catalogued as rs147516120; called by muse, mutect2
- ZBED9 | c.3184T>C p.L1062= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV71729492; called by muse, mutect2, varscan2
- ZNF101 | c.732T>A p.V244= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV58909158; called by muse, mutect2, varscan2
- ZNF70 | c.651C>T p.I217= | Silent (SNP) | VAF 49/253 reads (19%) | catalogued as COSV59533102; called by muse, mutect2, varscan2
- MAP2 | c.4585-961A>T | Intron (SNP) | VAF 51/198 reads (26%) | catalogued as COSV52295083; called by muse, mutect2, varscan2
- MIR890 | n.12A>T | RNA (SNP) | VAF 34/92 reads (37%) | called by muse, mutect2, varscan2
- NDUFV1 | chr11:67604711 G>C | 5'Flank (SNP) | VAF 84/337 reads (25%) | called by muse, mutect2, varscan2
